Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4620, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4620-01A (Primary Tumor).

[page 1 of 2]
Diagnosis:

kidney, left, nephrectomy and adrenalectomy

Tumor histologic type/subtype: renal cell carcinoma, clear cell subtype

Histologic grade (if applicable): 2 (of 4, Fuhrman classification)

Tumor size: 6.2 cm

Extent of invasion: through capsule into perirenal fat, posterior (A5) and perihilar (A9)

Vascular invasion: present, renal vein

Intraepithelial abnormality: n/a

Surgical margins: not involved

Lymph nodes: 0/2

Other organs: adrenal, left no carcinoma identified

AJCC Stage: pT3a pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

a renal mass.

Gross Description:

Specimen A is labeled "left kidney".

Specimen fixation:

Type of specimen: Radical nephrectomy

Side of specimen: Left

Size and weight of specimen: 600 grams; overall dimensions of 25 x 12 x 9 cm composed of a 10 x 8 x 6 cm kidney, 3.5 x 2.5 x 0.6 cm fragment of adrenal and perinephric fat and 4.5 x 0.4 cm of attached ureter.

Orientation: The external surface is marked with blue ink and the adrenal is marked with yellow ink.

Presence/absence of adrenal gland: Present, 3.5 x 2.5 cm fragment.

Tumor description/site: The tumor is a fleshy friable dark red/brown mass with a polypoid component extending into the renal pelvis. The tumor is predominantly located in the central medial aspect along the posterior surface. The mass has overlying adherent blood clot which extends into the renal pelvis. The blood clot overlies the polypoid component of the tumor which extends into the renal pelvis and focally into the ureter. The distal ureter does not appear obstructed. The renal pelvis is slightly dilated. The tumor also has a polypoid component extending into the renal vein (A2).

Tumor size: 6.2 x 4.3 x 3.5 cm. This is the overall tumor dimension. The polypoid component extending into the pelvis is 3.5 x 2.2 x 1.8 cm.

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Focally appears to extend into the perirenal fat along the posterior lateral aspect. Otherwise confined to the kidney.

Extent of invasion:

Perirenal adipose tissue: Suspicious posteriorly

Gerota's fascia: Negative

Renal vein: Polypoid tumor growth within the lumen not necessarily adherent to the vascular wall

Ureter: Polypoid tumor growth of blood clot into the ureter, loosely adherent.

Other organs: The adrenal gland is grossly unremarkable and uninvolved.

Surgical margins:

Perirenal adipose tissue: Tumor comes within 0.3 cm of the posterior lateral blue inked soft tissue margin.

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: Pale pink/tan with no cortical lesions identified. The remaining pelvic

[page 2 of 2]
urothelium is glistening white/pink.

Lymph nodes (hilar): None identified, but representative from hilar fat is submitted.

Other significant findings: None

Tissue submitted for special investigations: Tumor and normal are given to tissue procurement.

Digital photograph taken: No

Block Summary:

- A1 - Vascular and ureter margins of resection
- A2 - Perpendicular section of tumor growing into renal vein at hilum
- A3 - Adrenal gland
- A4 - Tumor and overlying urothelium
- A5 - Tumor in relationship to posterior fat and blue inked margin
- A6 - Tumor and adjacent parenchyma
- A7 - Polypoid component of tumor
- A8 - Additional section of tumor posteriorly extending into the perinephric fat and the blue inked surgical margin
- A9 - Additional section of tumor towards hilar structures
- A10 - Section of tumor with adjacent blood clot and parenchyma
- A11 - Central tumor
- A12 - Representative from normal appearing parenchyma inferior pole
- A13 - Representative sections from hilar fat

Source: NCI Genomic Data Commons file 65805cd2-f276-46ee-80a0-808089ae01f0 (TCGA-B8-4620.57336802-DDD7-46C3-98FC-92407721A34E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).